Somatic mutation profile of tumor specimen 0DH291 from CCDI case PBBUEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.6 years (2,769 days).
Specimen 0DH291: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e79341b-98bd-4673-a8c2-a3f2ac1e9c02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH27I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d68706d-aba6-479b-8d92-2092286b5b1d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 3, Missense Mutation 3, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LYL1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 105/544 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs749120126; called by muse, mutect2, varscan2
- SYT4 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 265/522 reads (51%) | catalogued as COSV54900669; called by muse, mutect2, varscan2
- ZNRF4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 105/230 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs761642041; called by muse, varscan2
- GJA10 | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 203/527 reads (39%) | called by muse, mutect2, varscan2
- PLCB1 | c.3506T>C p.M1169T | Missense Mutation (SNP) | VAF 373/826 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- USP9X | c.4933A>T p.R1645* | Nonsense Mutation (SNP) | VAF 329/384 reads (86%) | called by muse, mutect2, varscan2
- OSBP2 | c.2448G>A p.A816= | Silent (SNP) | VAF 252/535 reads (47%) | catalogued as rs745664497; called by muse, mutect2, varscan2
- TLE6 | c.*8C>T | 3'UTR (SNP) | VAF 106/202 reads (52%) | catalogued as rs370152123; called by muse, mutect2, varscan2
